Surgical pathology report (de-identified scan), TCGA case TCGA-43-3394, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-3394-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Left lower lobe
- B. Level 9
- C. Level 11
- D. Level 5

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung cancer.

GROSS DESCRIPTION

A. Received fresh subsequently fixed in formalin labeled "left lower lobe" is a 15 x 14 x 10 cm lobe of lung, which is partially covered with pink-gray smooth glistening pleura, which is stippled with black discoloration. The specimen shows a 10 cm stapled margin near the hilum. There is a firm focus on the pleura.

The focus is inked black and the specimen is sectioned to show a 4.5

x 4.5 x 4 cm pink-tan-white firm tumor, which appears centrally necrotic. This comes within 1.2 cm of the pleura and 3 cm from the bronchial margin. This also comes within 2 cm of the surgical margin at the hilum. The remainder of the cut surface is pink-red and spongy with no other discrete gross lesions identified. Few lymph nodes are grossly identified near the hilum. Representative sections of the specimen are submitted as follows:

BLOCK SUMMARY: 1 - Representative normal, 2 - tumor to pleura, 3 - tumor to normal, 4 - tumor to surgical margin (inked blue), 5 - tumor to bronchus, 6 - bronchial and vascular margins, 7 - possible hilar lymph node. RS-7.

B. Received fresh and subsequently fixed in formalin labeled "level 9" are two pink-red irregular soft tissue fragments, which are 0.7 x 0.5 x 0.4 cm and 0.5 x 0.2 x 0.1 cm. Specimens are entirely submitted. AS-1.

C. Received fresh and subsequently fixed in formalin

[page 2 of 3]
GROSS DESCRIPTION

labeled "level 11" are two black red irregular soft tissue fragments which are 1 cm and 0.5 cm in greatest dimension. The smaller tissue fragment is firm and hard. The specimens are entirely submitted in one cassette. AS-1.

D. Received fresh and subsequently fixed in formalin labeled "level 5" are multiple pink-red irregular soft tissue fragments, which have an aggregate measurement of 1.5 x 0.7

x

0.3 cm. Specimens are entirely submitted in one cassette. AS-1.

MICROSCOPIC DESCRIPTION

A. The following template applies to the left lower lobe

-

Histologic type: Squamous cell carcinoma.
Histologic grade: Poorly differentiated.
Primary tumor (pT): Measures 4.5 cm (pT2a)
Margins of resection: Uninvolved
Venous (large vessel) invasion: Not identified
Arterial (large vessel) invasion: Not identified
Lymphatic (small vessel) invasion: Not identified
Regional lymph nodes (pN): One lymph node with no metastasis.
Distant metastasis (pM): Cannot be evaluated by this specimen (pMX)
Other findings: None.

with B. The level 9 lymph node demonstrates one lymph node
no evidence of metastasis.
C. The level 11 lymph node demonstrates one lymph node
with no evidence of metastasis.
D. The level 5 lymph node demonstrates approximately 4

[page 3 of 3]
MICROSCOPIC DESCRIPTION

nodal fragments with no evidence of metastatic disease.

5, 3x3

DIAGNOSIS

- A. Lung, left lower lobe, resection:
- Squamous cell carcinoma, poorly differentiated, 4.5 cm in greatest dimension.
- Surgical margins uninvolved.
- One lymph node with no evidence of metastasis (0/1).
- B. Level 9 lymph node, resection: No evidence of metastatic disease in one lymph node (0/1).
- C. Level 11 lymph node, resection: No evidence of metastasis in one lymph node (0/1).
- D. Level 5 lymph node, resection: No evidence of metastasis in four node fragments (0/4).
-

--- End Of Report ---

Source: NCI Genomic Data Commons file b47d236e-9963-409f-bc46-27ca280283d9 (TCGA-43-3394.AB2C3289-581E-4BB2-A41F-418B057EF54B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).